Somatic mutation profile of tumor specimen C3N-02590-01 (aliquot CPT0187590022) from CPTAC case C3N-02590, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 68.5 years (25,019 days).
Specimen C3N-02590-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0affada-e678-4a65-9791-36e8c390b02f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02590-31 (Blood Derived Normal), aliquot CPT0187630002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ba687f3-a05c-48c7-9cb8-38edc34e749b

The open-access MAF lists 54 somatic variants for this specimen: 39 protein-altering or splice-affecting, 7 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 7, 3'UTR 3, Splice Region 3, Nonsense Mutation 2, Intron 2, Frame Shift Ins 2, Splice Site 2, RNA 1, 5'UTR 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 144/430 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1058A>C p.Y353S | Missense Mutation (SNP) | VAF 187/371 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs377767346, CM994757, COSV61688013; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.672+1G>A p.X224_splice | Splice Site (SNP) | VAF 157/239 reads (66%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ARHGEF7 | c.2510C>T p.A837V (on ENST00000646102 / NM_001354046.1; = p.A621V on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 106/353 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as COSV54542143; called by muse, mutect2, varscan2
- CAPN5 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 210/1030 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.576); catalogued as rs374497977; called by muse, mutect2, varscan2
- FAM47A | c.1555T>C p.S519P | Missense Mutation (SNP) | VAF 151/666 reads (23%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs867589029, COSV60496026; called by muse, varscan2
- FAM47A | c.1552C>G p.R518G | Missense Mutation (SNP) | VAF 145/659 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs17855514, COSV60495273, COSV60497171; called by muse, varscan2
- GRM6 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 130/399 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs1195558693; called by muse, mutect2, varscan2
- IARS2 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 34/418 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.076); catalogued as COSV56958476; called by muse, mutect2
- NEXMIF | c.3437C>A p.S1146Y | Missense Mutation (SNP) | VAF 186/611 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV50067061; called by muse, mutect2, varscan2
- NUP107 | c.497C>G p.S166C | Missense Mutation (SNP) | VAF 100/338 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as rs199858234; called by muse, mutect2, varscan2
- OTUD4 | c.217C>T p.R73* (on ENST00000447906 / NM_001366057.1; = p.R8* on NM_017493.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 117/336 reads (35%) | catalogued as COSV56849995; called by muse, mutect2, varscan2
- PRKAB1 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 133/443 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1319163692; called by muse, mutect2, varscan2
- RUFY4 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 163/556 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs1315662796; called by muse, mutect2, varscan2
- SARDH | c.1823C>T p.T608M | Missense Mutation (SNP) | VAF 140/452 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1471841676, COSV64100100; called by muse, mutect2, varscan2
- ZNF41 | c.956G>A p.S319N | Missense Mutation (SNP) | VAF 153/482 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV57442573; called by muse, mutect2, varscan2
- CACNA1S | c.589T>C p.F197L | Missense Mutation (SNP) | VAF 66/731 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- CELSR3 | c.3385G>A p.D1129N | Missense Mutation (SNP) | VAF 182/582 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CTAG2 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 319/1008 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ESCO1 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 444/725 reads (61%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBN1 | c.899A>T p.E300V | Missense Mutation (SNP) | VAF 131/392 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HDAC8 | c.1005G>A p.E335= | Splice Region (SNP) | VAF 105/349 reads (30%) | called by muse, mutect2, varscan2
- HKDC1 | c.1030A>T p.K344* | Nonsense Mutation (SNP) | VAF 111/300 reads (37%) | called by muse, mutect2, varscan2
- HUWE1 | c.646-7A>G | Splice Region (SNP) | VAF 112/319 reads (35%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 85/289 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LLGL2 | c.479C>A p.A160D | Missense Mutation (SNP) | VAF 331/489 reads (68%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MFHAS1 | c.317T>G p.V106G | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2
- MIB1 | c.2586+5_2586+15del p.X862_splice | Splice Site (DEL) | VAF 74/308 reads (24%) | called by mutect2, pindel, varscan2
- MINDY2 | c.631T>G p.L211V | Missense Mutation (SNP) | VAF 66/553 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.026); called by mutect2, varscan2
- MOK | c.372_374del p.F125del | In Frame Del (DEL) | VAF 24/119 reads (20%) | called by mutect2, pindel, varscan2
- MTA1 | c.1935del p.R646Gfs*3 | Frame Shift Del (DEL) | VAF 279/931 reads (30%) | called by mutect2, pindel, varscan2
- N4BP2L2 | c.1282_1289dup p.I430Mfs*48 | Frame Shift Ins (INS) | VAF 68/278 reads (24%) | called by mutect2, varscan2
- NT5C | c.466_467dup p.S157Qfs*36 | Frame Shift Ins (INS) | VAF 202/370 reads (55%) | called by mutect2, pindel, varscan2
- P2RX2 | c.1115T>C p.L372S | Missense Mutation (SNP) | VAF 203/627 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PARP4 | c.3288A>T p.A1096= | Splice Region (SNP) | VAF 109/285 reads (38%) | called by muse, mutect2
- PPEF2 | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 115/323 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- RANBP2 | c.3965T>C p.I1322T | Missense Mutation (SNP) | VAF 190/520 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERINC4 | c.781A>G p.S261G | Missense Mutation (SNP) | VAF 160/478 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TAMALIN | c.751G>T p.G251C | Missense Mutation (SNP) | VAF 203/579 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ACOT12 | c.1527C>T p.Y509= | Silent (SNP) | VAF 34/281 reads (12%) | called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1440G>A p.V480= | Silent (SNP) | VAF 150/451 reads (33%) | called by muse, mutect2, varscan2
- MYCBP2 | c.8529C>T p.L2843= (on ENST00000357337; = p.L2881= on NM_015057.5) | Silent (SNP) | VAF 48/455 reads (11%) | catalogued as rs754283675; called by muse, mutect2
- NXPE1 | c.214A>C p.R72= | Silent (SNP) | VAF 60/488 reads (12%) | called by muse, mutect2, varscan2
- PALB2 | c.828C>T p.H276= | Silent (SNP) | VAF 118/394 reads (30%) | catalogued as rs911713488, COSV55166306; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RFX1 | c.2478C>T p.D826= | Silent (SNP) | VAF 275/822 reads (33%) | catalogued as rs1200947508; called by muse, mutect2, varscan2
- SALL3 | c.2454G>A p.P818= | Silent (SNP) | VAF 308/592 reads (52%) | catalogued as rs1252378463; called by muse, varscan2
- AC136628.2 | n.90C>G | RNA (SNP) | VAF 18/121 reads (15%) | catalogued as rs28517507; called by muse, varscan2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 28/360 reads (8%) | catalogued as rs73150876; called by muse, mutect2
- IMPDH1 | c.*7C>T | 3'UTR (SNP) | VAF 162/314 reads (52%) | catalogued as rs375608202; called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442398 G>A | 3'Flank (SNP) | VAF 103/299 reads (34%) | catalogued as rs762382967; called by muse, mutect2, varscan2
- PPP6R3 | c.1343+19dup | Intron (INS) | VAF 22/135 reads (16%) | called by mutect2, varscan2
- TESC | c.-103C>A | 5'UTR (SNP) | VAF 47/150 reads (31%) | called by muse, mutect2, varscan2
- UVSSA | c.*9522G>A | 3'UTR (SNP) | VAF 282/815 reads (35%) | catalogued as rs765989288, COSV61351352; called by muse, mutect2, varscan2
- WDR45 | c.*102G>C | 3'UTR (SNP) | VAF 48/396 reads (12%) | catalogued as rs943051326, COSV59876297; called by muse, mutect2
